Somatic mutation profile of tumor specimen TARGET-10-PAPAXH-09A (aliquot TARGET-10-PAPAXH-09A-01D) from TARGET case TARGET-10-PAPAXH, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.7 years (983 days).
Specimen TARGET-10-PAPAXH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1b9a15be-752d-488d-a485-6cc543d9c19f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPAXH-14A (Bone Marrow Normal), aliquot TARGET-10-PAPAXH-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/16ca8e70-88dd-4414-ba38-9e25170dc9a8

The open-access MAF lists 18 somatic variants for this specimen: 9 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 5, Intron 3, RNA 1, In Frame Ins 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASPM | c.2987G>A p.R996K | Missense Mutation (SNP) | VAF 15/213 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs540157512; called by muse, mutect2
- ATP10D | c.2240G>A p.R747Q | Missense Mutation (SNP) | VAF 63/124 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146146861; called by muse, mutect2, varscan2
- AVEN | c.553C>T p.R185* | Nonsense Mutation (SNP) | VAF 20/43 reads (47%) | catalogued as rs766300982, COSV60734025; called by muse, mutect2, varscan2
- SPACA3 | c.307G>T p.G103W | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52191162; called by muse, mutect2, varscan2
- HECTD1 | c.746_747insGGAAAG p.G249_P250insER | In Frame Ins (INS) | VAF 25/68 reads (37%) | called by mutect2, pindel, varscan2
- KCNJ3 | c.914C>A p.T305K | Missense Mutation (SNP) | VAF 67/186 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- PXDNL | c.3439G>A p.D1147N | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UGT2A3 | c.225G>T p.E75D | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- ZNF600 | c.1469_1470insGG p.I491Efs*20 | Frame Shift Ins (INS) | VAF 94/279 reads (34%) | called by mutect2, pindel, varscan2
- FAT1 | c.9147C>T p.D3049= | Silent (SNP) | VAF 86/183 reads (47%) | catalogued as rs747040724, COSV71673153; called by muse, mutect2, varscan2
- MUC5AC | c.14355C>T p.N4785= | Silent (SNP) | VAF 25/293 reads (9%) | catalogued as rs748789084, COSV64368866; called by muse, mutect2
- NTAQ1 | c.150T>C p.C50= | Silent (SNP) | VAF 5/73 reads (7%) | called by muse, mutect2
- OR1N1 | c.732C>T p.C244= | Silent (SNP) | VAF 32/86 reads (37%) | catalogued as rs372806915; called by muse, mutect2, varscan2
- SLC6A17 | c.2145C>T p.S715= | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as rs151260028; ClinVar: likely benign; called by muse, mutect2, varscan2
- CLEC12A | c.10+86C>G | Intron (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2
- CUBNP3 | n.1664G>C | RNA (SNP) | VAF 75/161 reads (47%) | called by muse, mutect2, varscan2
- E2F4 | c.136-68A>C | Intron (SNP) | VAF 15/21 reads (71%) | called by muse, mutect2
- OGDH | c.1206+103C>T | Intron (SNP) | VAF 19/44 reads (43%) | called by muse, mutect2, varscan2
